Somatic mutation profile of tumor specimen TCGA-ZG-A9L0-01A (aliquot TCGA-ZG-A9L0-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9L0, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.3 years (26,055 days).
Specimen TCGA-ZG-A9L0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52e3fcbf-abfd-4398-8f08-c0588ffd15fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9L0-10A (Blood Derived Normal), aliquot TCGA-ZG-A9L0-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f247556-2bab-4869-a6f7-8ae416b15193

The open-access MAF lists 40 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Frame Shift Del 3, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATRNL1 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1554882917, COSV100746443; called by muse, mutect2, varscan2
- C17orf80 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.6); catalogued as COSV52148286; called by muse, mutect2, varscan2
- C1orf53 | c.403A>C p.K135Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV100956466; called by muse, mutect2, varscan2
- CCNK | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV101110469; called by muse, mutect2, varscan2
- CIAO3 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99285028; called by muse, mutect2, varscan2
- CYP2C18 | c.475A>C p.T159P | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1297881774, COSV53671371; called by muse, mutect2, varscan2
- DNMT3B | c.1647C>A p.F549L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.201); catalogued as rs773958724, COSV52414912; called by muse, mutect2, varscan2
- EIF4G3 | c.2843G>A p.R948H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1396933783, COSV99944938; called by muse, mutect2, varscan2
- FBXO45 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.349); catalogued as rs1051984466, COSV100291043; called by muse, mutect2, varscan2
- HNRNPDL | c.383A>T p.N128I | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV99787157; called by muse, mutect2, varscan2
- ITM2A | c.113A>G p.E38G | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs1360197652, COSV100964476; called by muse, mutect2, varscan2
- MYH9 | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99339330; called by muse, mutect2, varscan2
- OR2M4 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100141392; called by muse, mutect2
- PCDHB15 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs147410183, COSV50872050; called by muse, mutect2, varscan2
- PPP1R12A | c.2707T>G p.S903A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.036); catalogued as COSV99700580; called by muse, mutect2
- PRDX1 | c.276G>C p.K92N | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99423659; called by muse, mutect2, varscan2
- R3HDML | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.096); catalogued as COSV99407206; called by muse, varscan2
- RAI14 | c.216G>T p.M72I | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.977); catalogued as COSV99463919; called by muse, mutect2
- SERPINA3 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs375245228; called by muse, mutect2, varscan2
- SPOP | c.260A>T p.Y87F | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV100753468, COSV61652670, COSV61653014; called by muse, mutect2, varscan2
- TMEM106A | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.138); catalogued as COSV100357917; called by muse, mutect2, varscan2
- TRPM3 | c.1769G>A p.R590H (on ENST00000357533 / NM_001366142.2; = p.R423H on NM_020952.6) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100677851; called by muse, mutect2, varscan2
- ZMYM3 | c.3880C>T p.R1294C | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879255361, COSV100078128; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF578 | c.634T>G p.F212V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV101405086; called by muse, mutect2, varscan2
- ZNF800 | c.1609C>T p.H537Y | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99758044; called by muse, mutect2, varscan2
- ANOS1 | c.1708del p.S570Lfs*13 | Frame Shift Del (DEL) | VAF 24/43 reads (56%) | called by mutect2, pindel, varscan2
- CHRNA6 | c.1171_1172del p.H391Sfs*2 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | called by mutect2, pindel, varscan2
- KMT2D | c.7529del p.V2510Afs*33 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- DNAH17 | c.10356C>A p.I3452= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV101102834, COSV67756824; called by muse, mutect2, varscan2
- GRIA4 | c.1443C>A p.I481= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV56888896, COSV99233135; called by muse, mutect2, varscan2
- GRIP2 | c.195C>T p.T65= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs549750703; called by muse, mutect2, varscan2
- HELZ | c.5286C>T p.I1762= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100698895; called by muse, mutect2, varscan2
- IFT52 | c.492C>A p.L164= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100887638; called by muse, mutect2, varscan2
- SLC4A3 | c.3177G>A p.A1059= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs138004203, COSV56091427; called by muse, mutect2, varscan2
- SOX6 | c.2106C>T p.G702= (on ENST00000528429 / NM_001145819.2; = p.G675= on NM_017508.3) | Silent (SNP) | VAF 51/182 reads (28%) | catalogued as COSV100322653; called by muse, mutect2, varscan2
- ZFP36 | c.663C>G p.P221= (on ENST00000594442; = p.P215= on NM_003407.5) | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as rs149138506; called by muse, mutect2, varscan2
- ZNF117 | c.1062T>C p.I354= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as COSV99275882; called by muse, mutect2
- ZNF695 | c.1332T>G p.A444= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100377595; called by muse, mutect2, varscan2
- CHD4 | c.4642+73C>T | Intron (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100538478; called by muse, mutect2, varscan2
